Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A3VG, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A3VG-01A (Primary Tumor).

[page 1 of 3]
Head & Neck
Head And Neck

Date of Procedure:
Date of Receipt:
Date of Report:
Account #:
Billing Type:
Additional Copy to:

Clinical Diagnosis & History:

year ok with history of thyroid nodule FNA CW left nodule-atypical cells follicular, B. nodules on ultrasound.

Specimens Submitted:

- 1: SP: Thyroid, left lobe and isthmus, hemithyroidectomy
- 2: SP: Right thyroid lobe

DIAGNOSIS:

1. SP: Thyroid, left lobe and isthmus, hemithyroidectomy:

Tumor Type:

Papillary carcinoma, follicular variant

99% follicular variant per TSS / hr

Histologic Grade:

Well differentiated

Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Tumor Location:

Left lobe

Tumor Size:

Greatest diameter is 1.1 cm.

Tumor Encapsulation:

Completely surrounded

Capsular Invasion:

Not identified

Blood Vessel Invasion:

Not identified

Extrathyroid Extension:

Not identified

Surgical Margins:

Free of tumor

Tumor Multicentricity:

Not identified

Non-Neoplastic Thyroid:

Exhibits nodular hyperplasia

21

ICD-0-3

carcinoma, papillary, follicular variant

8340/3

Site: thyroid, NOS

C73.9

5-2-12

RO

[page 2 of 3]
Parathyroid Glands:
Not identified

2. Thyroid, right lobe, completion thyroidectomy:
-Thyroid with nodular hyperplasia
-No parathyroid glands are identified
-One benign lymph node (0/1)

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically signed Out ***

Gross Description:

1. The specimen is received fresh, labeled "left thyroid lobe and isthmus". It consists of a left thyroid lobe and portion of isthmus measuring 4.6 x 2.9 x 0.7 cm and weighing 7 g. The surface is smooth. The lobe is inked black posterior, blue anterior, and the area of the isthmus yellow. Serial sectioning reveals two nodules 0.3 cm away from each other in the mid to lower thyroid measuring 1.1 x 0.8 x 0.7 (arbitrarily designated N1) and 0.6 x 0.6 x 0.5 cm (arbitrarily designated N2). The first nodule appears well-circumscribed, solid, tan, firm, and bulges out of the surrounding thyroid parenchyma, 0.1 cm away from the anterior thyroid surface. s submitted from the first nodule (N1). Cut section of the second nodule shows a non-descript pale appearance, resembling nodular thyroid parenchyma. The remaining thyroid parenchyma is red and beefy. The specimen is entirely submitted. A photograph is taken of Nodule 1.

Summary of sections:

N1 - nodule 1 and surrounding thyroid tissue

N2 - nodule 2

S - superior thyroid

M - mid thyroid

2. The specimen is received fresh, labeled "Right thyroid lobe". It consists of a right thyroid lobe measuring 5.4 x 2.3 x 1.3 cm and weighing 9 g. The surface is smooth. The lobe is inked black posterior, blue anterior, and the area of the isthmus yellow. Serial sectioning reveals a tan- red, well-circumscribed nodule in the mid thyroid measuring 0.4 x 0.3 x 0.3 cm which is 0.3 cm from the anterior thyroid surface. The remaining thyroid parenchyma is mostly red and beefy. The specimen is entirely submitted.

Summary of sections:

N - nodule

S - superior thyroid

M - mid thyroid

I - inferior thyroid

Summary of Sections:

Part 1: SP: Thyroid, left lobe and isthmus, hemithyroidectomy

Block	Sect. Site	PCs
2	M	2
2	N1	2
3	N2	4
1	S	1

Part 2: SP: Right thyroid lobe

Block	Sect. Site	PCs
3	I	3
3	M	3
1	N	1

[page 3 of 3]
5

8

5

Source: NCI Genomic Data Commons file 47060413-4e83-4707-8a53-a3eee820b5b5 (TCGA-DJ-A3VG.5810F25F-31D6-4A52-9569-57AD6E4153DF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).